Somatic mutation profile of tumor specimen MMRF_1651_1_BM_CD138pos (aliquot MMRF_1651_1_BM_CD138pos_T1_KBS5U_L04401) from MMRF case MMRF_1651, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.2 years (19,793 days).
Specimen MMRF_1651_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91c568cd-b6ad-4a9f-95ac-d5c69be1a313.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1651_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1651_1_PB_Whole_C3_KBS5U_L04405; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/470bb646-79c3-48d6-9359-40f704d35d79

The open-access MAF lists 97 somatic variants for this specimen: 36 protein-altering or splice-affecting, 13 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 28, Silent 13, Intron 10, 5'UTR 6, 3'Flank 3, Frame Shift Del 3, RNA 1, Frame Shift Ins 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FSTL4 | c.2369dup p.T791Yfs*36 | Frame Shift Ins (INS) | VAF 50/76 reads (66%) | catalogued as rs765771244; called by mutect2, varscan2
- GSTA5 | c.28T>C p.S10P | Missense Mutation (SNP) | VAF 212/321 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs778816311; called by muse, mutect2, varscan2
- HBM | c.181C>A p.R61S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs749670088; called by muse, mutect2, varscan2
- IGHV2-70 | c.296T>G p.V99G | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755372451; called by muse, varscan2
- IGLV2-23 | c.149G>C p.S50T | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs372411137; called by muse, varscan2
- IGLV4-60 | c.120G>C p.K40N | Missense Mutation (SNP) | VAF 61/63 reads (97%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs186692431; called by muse, varscan2
- IGLV4-60 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 45/52 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs138271962; called by muse, varscan2
- IGLV4-60 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 48/54 reads (89%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs565260733; called by muse, varscan2
- MGAM | c.5141del p.G1714Afs*11 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | catalogued as COSV72074223; called by mutect2, pindel, varscan2
- PTPRT | c.2000A>G p.E667G | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV61968975; called by muse, mutect2, varscan2
- SRRM4 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs901555516; called by muse, mutect2, varscan2
- STK17A | c.160C>G p.P54A | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV60046152; called by muse, mutect2, varscan2
- STK35 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs895822739; called by muse, mutect2, varscan2
- STK39 | c.1610T>C p.I537T | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs1158204214; called by muse, mutect2, varscan2
- TLR2 | c.1735C>T p.R579C | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs751131041, COSV52605923; called by muse, mutect2, varscan2
- ANKRD13C | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 49/50 reads (98%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CAMTA1 | c.4811A>G p.Y1604C | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPS2 | c.648+4A>C | Splice Region (SNP) | VAF 67/105 reads (64%) | called by muse, mutect2, varscan2
- CYP8B1 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXO24 | c.222_223del p.D74Efs*76 (on ENST00000241071 / NM_033506.3; = p.D112Efs*76 on NM_012172.5) | Frame Shift Del (DEL) | VAF 49/74 reads (66%) | called by mutect2, pindel, varscan2
- FREM1 | c.2556T>A p.H852Q | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FRY | c.8407A>G p.T2803A | Missense Mutation (SNP) | VAF 45/47 reads (96%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GASK1B | c.1214A>G p.D405G | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GRWD1 | c.363_382del p.S122Gfs*3 | Frame Shift Del (DEL) | VAF 35/80 reads (44%) | called by mutect2, varscan2
- IGHV2-70D | c.171G>T p.W57C | Missense Mutation (SNP) | VAF 20/21 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- IGHV2-70D | c.136T>G p.F46V | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); called by muse, varscan2
- KIF12 | c.1912A>G p.S638G (on ENST00000640217; = p.S500G on NM_138424.1) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIF19 | c.750_752del p.D250_L251delinsE | In Frame Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- NSUN4 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NUBP1 | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- RGS22 | c.2536G>A p.A846T | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- SLC40A1 | c.495A>C p.E165D | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- STIP1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ZBTB41 | c.227A>T p.Y76F | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF324B | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ZNF608 | c.2668A>G p.T890A | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ARFGEF3 | c.5979A>G p.K1993= | Silent (SNP) | VAF 56/83 reads (67%) | called by muse, mutect2, varscan2
- BCL9L | c.2007C>T p.F669= | Silent (SNP) | VAF 45/86 reads (52%) | called by muse, mutect2, varscan2
- FKBP10 | c.1131G>A p.A377= | Silent (SNP) | VAF 50/84 reads (60%) | catalogued as rs140883737; called by muse, mutect2, varscan2
- HECW1 | c.105C>T p.C35= | Silent (SNP) | VAF 54/84 reads (64%) | called by muse, mutect2, varscan2
- IGHE | c.192T>C p.G64= | Silent (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- IGKV4-1 | c.34T>C p.L12= | Silent (SNP) | VAF 15/15 reads (100%) | catalogued as rs756892595; called by muse, mutect2, varscan2
- OR14K1 | c.558T>C p.T186= | Silent (SNP) | VAF 52/119 reads (44%) | catalogued as COSV51721619; called by muse, mutect2, varscan2
- PPP1R12A | c.1581A>T p.S527= | Silent (SNP) | VAF 21/141 reads (15%) | called by muse, mutect2, varscan2
- PTPRF | c.4191C>T p.I1397= | Silent (SNP) | VAF 56/148 reads (38%) | catalogued as rs759751048, COSV63445849, COSV63447488; called by muse, mutect2, varscan2
- SDC3 | c.252G>T p.S84= | Silent (SNP) | VAF 19/125 reads (15%) | called by muse, mutect2, varscan2
- SHC4 | c.1605G>A p.A535= | Silent (SNP) | VAF 60/88 reads (68%) | catalogued as rs141070519; called by muse, mutect2, varscan2
- SMAD7 | c.231G>C p.P77= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs1045669229; called by muse, mutect2, varscan2
- VIRMA | c.1396C>T p.L466= | Silent (SNP) | VAF 53/100 reads (53%) | called by muse, mutect2, varscan2
- ABCA2 | c.*397C>T | 3'UTR (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- C2orf91 | n.1803A>G | RNA (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2, varscan2
- COPS5 | c.144-1084G>A | Intron (SNP) | VAF 69/142 reads (49%) | called by muse, mutect2, varscan2
- CREM | chr10:35212811 A>T | 3'Flank (SNP) | VAF 11/90 reads (12%) | called by muse, mutect2, varscan2
- CRTAP | c.*923A>G | 3'UTR (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- FCRL5 | c.1681+710G>A | Intron (SNP) | VAF 75/144 reads (52%) | called by muse, mutect2, varscan2
- FOXK1 | c.*8520C>T | 3'UTR (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
- FUBP3 | c.*504A>T | 3'UTR (SNP) | VAF 39/68 reads (57%) | called by muse, mutect2, varscan2
- GABRA6 | c.225+355A>G | Intron (SNP) | VAF 43/56 reads (77%) | called by muse, mutect2, varscan2
- GALNT17 | c.*1034A>G | 3'UTR (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- GALNTL5 | c.-28_-14del | 5'UTR (DEL) | VAF 136/270 reads (50%) | called by mutect2, varscan2
- GCG | chr2:162143182 T>G | 3'Flank (SNP) | VAF 67/142 reads (47%) | called by muse, mutect2, varscan2
- GCLM | c.*3625A>G | 3'UTR (SNP) | VAF 35/39 reads (90%) | called by muse, mutect2, varscan2
- GNPNAT1 | c.*809A>G | 3'UTR (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- GPM6A | c.*1830T>A | 3'UTR (SNP) | VAF 52/96 reads (54%) | called by muse, mutect2, varscan2
- GPR156 | c.*1005T>A | 3'UTR (SNP) | VAF 55/126 reads (44%) | called by muse, mutect2, varscan2
- GSTM4 | c.*65C>T | 3'UTR (SNP) | VAF 124/284 reads (44%) | catalogued as rs1279731927; called by muse, mutect2, varscan2
- HSPA4L | c.*1308G>A | 3'UTR (SNP) | VAF 24/42 reads (57%) | called by muse, varscan2
- IGHV1-2 | c.-20T>A | 5'UTR (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- INTS8 | c.*397C>T | 3'UTR (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- KLF13 | c.*315A>T | 3'UTR (SNP) | VAF 44/131 reads (34%) | called by muse, mutect2, varscan2
- KPNA4 | c.*1756T>A | 3'UTR (SNP) | VAF 57/127 reads (45%) | catalogued as rs1393815006; called by muse, mutect2, varscan2
- LAMTOR4 | c.203-98A>G | Intron (SNP) | VAF 42/214 reads (20%) | called by muse, mutect2, varscan2
- LRBA | c.4569+3064T>C | Intron (SNP) | VAF 38/86 reads (44%) | called by muse, mutect2, varscan2
- MYO1E | c.-206C>G | 5'UTR (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- NCKAP5 | c.341+6935T>C | Intron (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
- NUAK1 | c.*1288T>G | 3'UTR (SNP) | VAF 84/130 reads (65%) | called by muse, mutect2, varscan2
- OPRK1 | c.*2824C>T | 3'UTR (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- PAIP1 | c.*1092A>T | 3'UTR (SNP) | VAF 62/210 reads (30%) | called by muse, mutect2, varscan2
- PCDH10 | c.*615A>C | 3'UTR (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- PCDH9 | c.*1531del | 3'UTR (DEL) | VAF 12/24 reads (50%) | called by mutect2, varscan2
- PCDH9 | c.*1530A>C | 3'UTR (SNP) | VAF 12/23 reads (52%) | catalogued as rs987213033; called by mutect2, varscan2
- PDE7B | c.711+179A>T | Intron (SNP) | VAF 33/106 reads (31%) | called by muse, mutect2, varscan2
- PHF3 | c.*6396A>C | 3'UTR (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- RBM12B | c.*2905C>T | 3'UTR (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- SEC61G | c.-53A>T | 5'UTR (SNP) | VAF 24/149 reads (16%) | called by muse, mutect2, varscan2
- SH3PXD2A | c.*2167T>C | 3'UTR (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- SLC12A1 | c.628+2148G>A | Intron (SNP) | VAF 87/134 reads (65%) | called by muse, mutect2, varscan2
- SLC22A15 | c.*1730A>C | 3'UTR (SNP) | VAF 63/124 reads (51%) | called by muse, mutect2, varscan2
- SPRY4 | c.*1241del | 3'UTR (DEL) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- SYNPR | c.-313G>A | 5'UTR (SNP) | VAF 23/42 reads (55%) | catalogued as rs970703794; called by muse, mutect2, varscan2
- TERF1 | c.888-95del | Intron (DEL) | VAF 5/14 reads (36%) | called by mutect2, varscan2
- TFAP2A | chr6:10397029 ins A | 3'Flank (INS) | VAF 62/150 reads (41%) | catalogued as rs79168174; called by mutect2, varscan2
- TJP1 | c.*1619A>C | 3'UTR (SNP) | VAF 98/159 reads (62%) | called by muse, mutect2, varscan2
- VPS35 | c.2212-57G>T | Intron (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- WNT9A | c.*1814G>A | 3'UTR (SNP) | VAF 6/37 reads (16%) | catalogued as rs1222489327; called by muse, varscan2
- WTAP | c.-438C>T | 5'UTR (SNP) | VAF 58/84 reads (69%) | catalogued as rs1210523911; called by muse, mutect2, varscan2
- ZSCAN20 | c.*450_*463del | 3'UTR (DEL) | VAF 26/63 reads (41%) | called by mutect2, pindel, varscan2
